Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A44U, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A44U-01A (Primary Tumor).

Procurement Date: Laterality: Adenocarcinoma of the stomach, G-3, with invasion into the perigastric fat. Five examined lymph nodes form greater curvature and five examined lymph nodes form lesser curvature demonstrated metastases. In the omentum there is focal prevascular lymphoid infiltration.

Path Report: STOMACH TISSUE CHECKLIST

ICD-O-3

Specimen type: Subtotal gastrectomy

Adenocarcinoma, NOS
81401.3

Tumor site: Antrum

Site: Stomach, antrum

Tumor size: 4 x 0 x 6 cm

8-31-12
RD

C16.3

Tumor features: Ulcerated

Histologic type: Adenocarcinoma ✓

Histologic grade: Poorly differentiated

Tumor extent: Subserosa

Lymph nodes: 10/15 positive for metastasis (Greater and lesser omentum 10/15)

Lymphatic invasion: Present

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 94ab2edc-6fbd-4a8e-a58f-588c19a2c757 (TCGA-BR-A44U.82CA5CB5-68B4-490E-AF2F-FE66A6F915C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).